Surgical pathology report (de-identified scan), TCGA case TCGA-77-8139, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8139-01A (Primary Tumor).

[page 1 of 2]
Collected [REDACTED]

Histopathology Report

HISTORY
RUL cancer.

MACROSCOPIC
Two specimens submitted.

1: The first specimen is labelled "right upper lobe" and consists of a lobectomy specimen of lung measuring approximately 180 x 120 x 36 mm. The bronchial resection margin measures approximately 15 mm in external diameter. Peripherally within the specimen there is an ill-defined firm mass palpable within the lung with attachment to adjacent parietal pleura and a portion of three ribs which range in length from 38 mm to 75 mm. Elsewhere the pleura appears normal. The tumour is at least 55 mm in diameter and extensively invades the intercostal soft tissue including muscle. The lesion however appears clear of the soft tissue resection margins. The tumour appears intimately associated with the periosteum of the longest rib segment centrally. [Shave of bronchial resection margin and peribronchial lymph nodes, 1A; shave of peribronchial vascular resection margin and section of peripheral normal lung, 1B; sections of tumour, 1C-1E; sections of tumour in relation to parietal pleura and chest wall, 1F-1I; TS of longest segment of rib in relation to tumour, 1J.]

2: The second specimen is labelled "lymph node hilar" and consists of multiple small lymph nodes and a single larger node measuring 14 mm in maximum extent. [Small nodes BIT-2A; larger node-2B.]

MICROSCOPIC

1: Sections show a moderately differentiated squamous cell carcinoma which invades the pleura and into soft tissue of the chest wall including intercostal muscle. The soft tissue resection margins are clear of malignancy. No vascular, lymphatic or perineural invasion is identified. Tumour stroma contains a heavy plasmacytic infiltrate but tumour-infiltrating lymphocytes are not prominent. The bronchial resection margin is well clear of malignancy but shows patchy squamous metaplasia and focal mild dysplasia. The lung parenchyma adjacent to the tumour shows patchy organising pneumonia. Distant lung parenchyma shows severe emphysema. The peribronchial lymph nodes show no evidence of metastatic carcinoma.

Report to follow on decalcified section of rib.

2: Sections show lymph nodes with reactive changes only. There is no evidence of metastatic carcinoma.

SUMMARY

Right upper lobectomy, chest wall resection and hilar lymph nodes sampling:

[page 2 of 2]
Collected [REDACTED]

Histopathology Report

Moderately differentiated squamous cell carcinoma, approx. 55 mm in diameter.
Chest wall invasion present; soft tissue resection margins clear of malignancy.
No vascular, lymphatic or perineural invasion found.
No lymph node metastases present.
Pathological stage T3 N0.

SUPPLEMENTARY REPORT

The decalcified section of rib shows no evidence of periosteal or bony invasion by carcinoma.

cc: Lung Cancer Registry

Source: NCI Genomic Data Commons file 71d008e2-b278-472a-bae6-c6623cb6bf1f (TCGA-77-8139.EBFD7BA3-0F3B-4C90-9D26-10A8394C01F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).